Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70K, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70K-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Retroperitoneal mass (1FS): Splenunculus.
2. Adrenal mass, right, excision: Pheochromocytoma. See Note.

NOTE: No vascular or capsular invasion seen. A lymph node search was performed in periadrenal adipose tissue and no lymph nodes were identified. The neoplastic cells are positive for chromogranin and synaptophysin and negative for inhibin. S100 stains sustentacular cells. This staining pattern is consistent with a pheochromocytoma.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: Pheochromocytoma
Specimen Taken For Protocol:
01 - Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: Large 10 X 9 X 8 cm right adrenal mass and a 2 X 1.5cm left splenule Post-Operative Diagnosis: Pheochromocytoma
Pre-Operative Diagnosis: Pheochromocytoma

SPECIMENS SUBMITTED: 1. RETROPERITONEAL MASS, Left (1FS)
2. ADRENAL GLAND, RIGHT

INTRAOPERATIVE CONSULTATION: Received fresh from the OR with the patient's name, medical record number, date of birth, and further specified as "left retroperitoneal mass" is an intact spherical nodule, maroon and smooth in color, 1.5 cm in diameter and is focally attached to pink-yellow adipose tissue separately measuring 1.2 x 0.8 x 0.8 cm. Diagnosis (1FS): Spleen. The intraoperative consultation was performed by

GROSS DESCRIPTION: Received fresh are 2 specimens, each in containers labeled with the patient's name, medical record number, and further specified as follows:

Received fresh from the OR in a container labeled with the patient's name, medical record number, and further

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 3]
Surgical Pathology

Received are 2 formalin-filled containers labeled with the patient's name, medical record number, and date of birth. These specimens are further specified as follows:

1. "Left retroperitoneal mass" are 2 fragments of tissue that appear in consistency and color to be that of splenic tissue. The first fragment is irregular, lobulated, 3 cm splenic tissue fragment that is placed into a white cassette labeled This tissue is placed into a white cassette labeled This tissue also corresponds to the specimen that was examined as a frozen section. The whole contents of the section examined during the intraoperative frozen section consultation are transferred from a green cassette labeled to an orange cassette labeled

2. "Right adrenal for resection-and-permanent" is a focally disrupted red ovoid nodular tissue fragment measuring 10 x 9 x 8 cm, and weighing 429 grams. It is focally covered by adipose tissue and the cortex of the adrenal gland that is evident. There is a 1 x 0.4-cm focal surgical defect on the external surface with pink-tan soft friable tumor fragments that appear to be tumor. It is bisected revealing a heterogeneous red-tan soft friable and rubbery cut surface with hemorrhage. The center of the mass has a rubbery to crumbly maroon-red necrotic center comprising 50% of the nodule. Gross photographs are taken. Approximately 60% of the viable portion of the nodule is procured for research with the majority going to and a 4-mm piece of tissue to The remainder of the specimen is placed into formalin and submitted to Pathology for permanent. Procurement was performed by on

Received in pathology is the above mentioned mass that is cut in a perpendicular fashion from the lateral to the medial side in order to improve fixation. The areas of necrotic tissue that appear to be consistent with a tumor are apparent on the lateral surface of the mass. On gross examination, there does appear to be normal adrenal gland which appears on one of the lateral surfaces and appears 4 cm in greatest diameter. The external surface of the entire mass has been inked black. Serial sections through the portion of the mass that appears to have adrenal gland in addition to tumor are sectioned and placed into cassettes

. represents the most lateral portion of the identified adrenal gland and serial sections are 1 cm apart and towards the medial aspect of the mass. The first section in does not appear to have any adrenal tissue on gross examination, however, the next section that will be placed in does appear to have normal adrenal tissue. The irregular mass is serially sectioned and placed into white cassettes labeled This area appears to be lateral to normal adrenal tissue. This portion of the mass is approximately 6 cm and extends from what appears to be the end of normal adrenal tissue all the way to the edge of the mass. Again, the capsule is inked black. A well-circumscribed white-tan lesion is located within the realm of a much more dark

[page 3 of 3]
Surgical Pathology [

Final Results

reddish brownish homogeneous material that encompasses most of the mass. This lesion is placed entirely into the white cassette

The most lateral portion of the mass is placed into white cassette labeled

Surrounding adipose tissue with the possibility of harboring lymph nodes are placed into white cassettes labeled:

An additional 1.5 cm white lesion that is well-circumscribed and within the larger mass that is very homogeneous and tan-brown in color is sectioned and placed into white cassette labeled

Gross Description dictated by :
Gross Description dictated by :

Additional

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Source: NCI Genomic Data Commons file 75518b30-b4bb-4353-974e-23c9b579833d (TCGA-QR-A70K.89446519-CC95-4244-9BCF-F37619D3618E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).